Somatic mutation profile of tumor specimen TCGA-L5-A43I-01A (aliquot TCGA-L5-A43I-01A-11D-A247-09) from TCGA case TCGA-L5-A43I, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 77.7 years (28,367 days).
Specimen TCGA-L5-A43I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 958b6525-2c92-43b0-a8de-cf3973cb4b9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A43I-11A (Solid Tissue Normal), aliquot TCGA-L5-A43I-11A-11D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd400845-0a37-44cb-8227-90d2f8438873

The open-access MAF lists 202 somatic variants for this specimen: 149 protein-altering or splice-affecting, 50 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 50, Nonsense Mutation 9, Splice Region 3, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 2, Intron 2, Translation Start Site 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAGI2 | c.1808T>G p.L603R | Missense Mutation (SNP) | VAF 4/49 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62636665, COSV62664406; called by muse, mutect2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 35/51 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC006059.2 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.112); catalogued as rs139169922; called by muse, mutect2, varscan2
- ADAM7 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs1173589877, COSV99444011; called by muse, mutect2, varscan2
- ADAMTS14 | c.2699G>A p.R900H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.166); catalogued as rs747059045, COSV64600275; called by muse, mutect2, varscan2
- ANKMY2 | c.1210C>G p.Q404E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as COSV61013114; called by muse, mutect2, varscan2
- ARHGAP31 | c.2368C>G p.P790A | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV99957084; called by muse, mutect2
- ASCC3 | c.4300G>T p.V1434F | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV64974247; called by muse, mutect2, varscan2
- BOLL | c.422A>G p.H141R | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs975681893; called by muse, mutect2
- BPTF | c.3210_3221del p.N1071_E1074del | In Frame Del (DEL) | VAF 20/74 reads (27%) | catalogued as rs749412697; called by mutect2, varscan2
- CCL7 | c.83T>G p.I28S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV52336811; called by muse, mutect2, varscan2
- CHD9 | c.6964G>A p.G2322S | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.81); PolyPhen benign (0.182); catalogued as rs201884816, COSV54614637; called by muse, mutect2, varscan2
- CHRD | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772596758, COSV52605599; called by muse, mutect2, varscan2
- CHRNA1 | c.1408G>A p.V470M (on ENST00000261007 / NM_001039523.3; = p.V445M on NM_000079.4) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs372104868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYB561D1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs751790976; called by muse, mutect2, varscan2
- DACH2 | c.761A>C p.N254T | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.11); PolyPhen benign (0.119); catalogued as COSV100912423; called by muse, mutect2, varscan2
- DCHS1 | c.5897G>A p.R1966H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as rs765681020; called by muse, varscan2
- DCLK2 | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1258552457; called by muse, mutect2, varscan2
- DSCAM | c.5302T>A p.W1768R | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68035534; called by muse, mutect2, varscan2
- DSCAML1 | c.1237G>A p.E413K (on ENST00000321322; = p.E353K on NM_020693.4) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.341); catalogued as COSV100355821, COSV58398914; called by muse, mutect2, varscan2
- ERBB4 | c.878G>A p.C293Y | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53533250; called by muse, mutect2, varscan2
- FRYL | c.8867C>T p.T2956M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as rs763784117, COSV51951786; called by muse, mutect2, varscan2
- GABBR1 | c.1721dup p.A575Sfs*2 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | catalogued as rs777471402; called by mutect2, varscan2
- HDAC9 | c.1978C>T p.R660* | Nonsense Mutation (SNP) | VAF 28/76 reads (37%) | catalogued as rs758672820, COSV67774088; called by muse, mutect2, varscan2
- HSPG2 | c.5084C>T p.S1695F | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65979176; called by muse, mutect2, varscan2
- IKZF1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV100498820, COSV100498905, COSV58791383; called by muse, mutect2, varscan2
- ITGAE | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs373069448; called by muse, mutect2, varscan2
- ITIH5 | c.1418+1G>T p.X473_splice | Splice Site (SNP) | VAF 13/110 reads (12%) | catalogued as rs776026691, COSV53668251; called by muse, mutect2, varscan2
- KCNJ12 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536297311, COSV59167203, COSV59169991; called by muse, mutect2, varscan2
- KRT6A | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs777982391; called by muse, mutect2, varscan2
- LRP1 | c.5978G>A p.R1993Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs948848252; called by muse, mutect2, varscan2
- LRP1B | c.3905T>G p.L1302R | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67218308; called by muse, mutect2, varscan2
- LVRN | c.1390dup p.S464Ffs*2 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | catalogued as rs756702147; called by mutect2, varscan2
- MAGEL2 | c.2642G>A p.R881H | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs368034669, COSV99041382; called by muse, mutect2, varscan2
- MUC16 | c.13718G>T p.S4573I | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs1397564851; called by muse, mutect2, varscan2
- NKAPL | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100642455; called by muse, mutect2, varscan2
- NRG1 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.042); catalogued as COSV99828277; called by muse, mutect2
- NRXN3 | c.665G>T p.R222L (on ENST00000557594 / NM_001272020.2; = p.R854L on NM_004796.6) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99816367; called by muse, mutect2, varscan2
- NUP153 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206158833; called by muse, mutect2
- OPA3 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs374639297; ClinVar: likely benign; called by muse, varscan2
- OR2L8 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs572027464, COSV61727514, COSV61727605; called by muse, mutect2, varscan2
- OR2T33 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775475303, COSV58813890; called by muse, mutect2, varscan2
- OR2T8 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs778031908, COSV60661344; called by mutect2, varscan2
- OR5AS1 | c.596T>G p.L199R | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57983368; called by muse, mutect2, varscan2
- OR5R1 | c.934T>G p.L312V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as rs570860563; called by mutect2, varscan2
- PCDHGA5 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs375711929; called by muse, mutect2, varscan2
- PCDHGB1 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs780182840, COSV53893504, COSV54007624; called by muse, mutect2, varscan2
- PHF14 | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs1173060518; called by muse, mutect2, varscan2
- PLVAP | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs151286294; called by muse, mutect2, varscan2
- PMPCA | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759251899, COSV100867799; called by muse, mutect2, varscan2
- PRSS37 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs146733171; called by muse, mutect2, varscan2
- RRH | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1006004651; called by muse, mutect2, varscan2
- RXFP1 | c.1436G>A p.W479* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as rs769493929; called by muse, mutect2, varscan2
- SCN5A | c.4913G>A p.R1638Q (on ENST00000333535 / NM_198056.3; = p.R1637Q on NM_000335.5) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs374557801, COSV61123571; called by muse, mutect2, varscan2
- SH3GL3 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61056981; called by muse, mutect2, varscan2
- SLC2A14 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs778496220, COSV61586827; called by muse, mutect2, varscan2
- SLC45A1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99238398; called by muse, mutect2
- SLC9C1 | c.1788A>T p.S596= | Splice Region (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99997483; called by muse, mutect2, varscan2
- SPAM1 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749343447, COSV56147094, COSV99773504; called by muse, mutect2, varscan2
- SPIRE2 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs754904770; called by muse, mutect2, varscan2
- SPTBN2 | c.3818G>A p.R1273H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs557577438, COSV59462984; called by muse, mutect2, varscan2
- ST3GAL1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 19/89 reads (21%) | PolyPhen probably damaging (0.948); catalogued as rs1233734180; called by muse, mutect2, varscan2
- TAGLN2 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.042); catalogued as rs1332089076; called by muse, mutect2, varscan2
- TECRL | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.176); catalogued as rs376067868; called by muse, mutect2, varscan2
- TGOLN2 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.993); catalogued as rs1367690342; called by muse, mutect2, varscan2
- TIAM2 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as rs766127122, COSV59694638; called by muse, mutect2, varscan2
- TMPRSS9 | c.2519C>T p.P840L (on ENST00000648592; = p.P806L on NM_182973.2) | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs777177113; called by muse, mutect2, varscan2
- TRAV20 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758301281; called by muse, mutect2, varscan2
- TRMU | c.1017A>G p.L339= | Splice Region (SNP) | VAF 16/57 reads (28%) | catalogued as rs1211097737; called by muse, mutect2, varscan2
- UBR4 | c.5522C>A p.A1841D | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1160517990; called by muse, mutect2, varscan2
- UBR5 | c.8134C>T p.R2712C | Missense Mutation (SNP) | VAF 114/148 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1247695494; called by muse, mutect2, varscan2
- USP35 | c.2918C>T p.A973V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs570683097, COSV60871135; called by muse, mutect2, varscan2
- VN1R2 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | PolyPhen benign (0.025); catalogued as rs111541974, COSV100447826; called by muse, mutect2, varscan2
- VPS50 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 6/63 reads (10%) | catalogued as rs776743041, COSV52492435; called by muse, mutect2, varscan2
- ZNF275 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 37/39 reads (95%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs782659392, COSV100936237; called by muse, mutect2, varscan2
- ZNF276 | c.1480C>T p.R494W (on ENST00000443381 / NM_001113525.2; = p.R419W on NM_152287.4) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765066482; called by muse, mutect2, varscan2
- ZNF566 | c.1243A>C p.N415H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV67574238; called by muse, mutect2, varscan2
- ZNF623 | c.25G>C p.D9H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV101513582, COSV71697185; called by muse, mutect2, varscan2
- ZNF681 | c.749G>C p.R250T | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV101267397, COSV68075523; called by muse, mutect2, varscan2
- ADCY10 | c.4589G>A p.C1530Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ANKZF1 | c.1612C>T p.L538F | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APOB | c.7070T>A p.L2357* | Nonsense Mutation (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
- ARF6 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.017); called by muse, mutect2
- ATP1B1 | c.828T>A p.C276* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- ATP2C1 | c.577A>C p.T193P | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.18); called by muse, mutect2
- BNC1 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BOLL | c.421C>A p.H141N | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2
- BRIP1 | c.1471C>A p.Q491K | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.974); called by muse, mutect2
- BTRC | c.1679G>A p.R560Q (on ENST00000370187 / NM_033637.4; = p.R524Q on NM_003939.5) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CCSER2 | c.2374G>A p.G792R | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CDHR3 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CDK13 | c.1604A>G p.D535G | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- CFAP206 | c.580A>C p.I194L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- CFAP47 | c.4810A>T p.K1604* | Nonsense Mutation (SNP) | VAF 25/43 reads (58%) | called by muse, mutect2, varscan2
- COMP | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CPXCR1 | c.636G>C p.M212I | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.028); called by mutect2, varscan2
- DHX36 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EPC2 | c.713G>A p.R238K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- EVC2 | c.410A>C p.K137T | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- EVI5L | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- FCSK | c.85C>T p.L29= | Splice Region (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- FURIN | c.1054-2A>C p.X352_splice | Splice Site (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- GUCY2C | c.3119C>G p.A1040G | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA10 | c.30_34delinsG p.F10Lfs*6 | Frame Shift Del (DEL) | VAF 53/134 reads (40%) | called by pindel, varscan2*
- ITPKB | c.2245A>T p.R749W | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNN2 | c.724G>T p.A242S (on ENST00000264773; = p.A454S on NM_021614.4) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- KMT2B | c.1072del p.E358Nfs*29 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- LAPTM5 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LRRIQ1 | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- LUZP2 | c.859-1G>C p.X287_splice | Splice Site (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- MACF1 | c.3998T>C p.L1333P | Missense Mutation (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- MASTL | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MGAT2 | c.1087A>C p.K363Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- MTR | c.912G>C p.M304I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- NCAM2 | c.2493A>C p.K831N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- NCAPD3 | c.2387G>T p.S796I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- NSD1 | c.3341T>A p.V1114D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- NUP98 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- OR4A15 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OXGR1 | c.304G>T p.G102* | Nonsense Mutation (SNP) | VAF 36/50 reads (72%) | called by muse, mutect2, varscan2
- PCDH10 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHA12 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHAC2 | c.1955G>T p.S652I | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- PCDHGA12 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCNX3 | c.2702G>A p.R901Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PDZK1IP1 | c.-7_8del | Translation Start Site (DEL) | VAF 18/40 reads (45%) | called by mutect2, varscan2
- PLAU | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PLXNB1 | c.600T>A p.Y200* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2
- PMP22 | c.145A>C p.N49H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PYROXD1 | c.827A>C p.K276T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RASGRP3 | c.698T>G p.L233R | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- RIMBP2 | c.2983G>C p.D995H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMS1 | c.4769A>T p.K1590M | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SACS | c.11236G>C p.D3746H | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- SLITRK3 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 33/61 reads (54%) | called by muse, mutect2, varscan2
- STK32A | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SUCO | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- TAF2 | c.2723A>G p.Q908R | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- THBD | c.1325T>G p.I442S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- TMEM74 | c.179T>G p.L60R | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- TPTE | c.1143A>T p.K381N (on ENST00000618007 / NM_199261.4; = p.K363N on NM_199259.4) | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TTN | c.33427C>G p.P11143A (on ENST00000591111; = p.P10216A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | PolyPhen benign (0.051); called by muse, mutect2, varscan2
- USP29 | c.2267G>A p.R756K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- USP31 | c.1847C>A p.A616D | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VWA3B | c.2372A>T p.E791V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- WDR72 | c.2773G>A p.V925I | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZMYM6 | c.197G>A p.G66D | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ZNF28 | c.1943C>T p.S648L | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZNF292 | c.3061T>A p.L1021I | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ACTRT1 | c.732A>G p.P244= | Silent (SNP) | VAF 24/30 reads (80%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.4203A>T p.V1401= | Silent (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- AFF3 | c.603C>T p.A201= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV57855198; called by muse, mutect2
- ANK2 | c.5652G>T p.S1884= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs1056627374, COSV52148616; called by muse, mutect2, varscan2
- ASPSCR1 | c.1338G>A p.T446= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as rs148162287; called by muse, varscan2
- BSN | c.9915C>T p.L3305= | Silent (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- CD1E | c.513G>C p.V171= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- CDK16 | c.1278G>A p.L426= | Silent (SNP) | VAF 24/34 reads (71%) | called by muse, mutect2, varscan2
- CELA1 | c.624C>T p.G208= | Silent (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- CHST5 | c.678G>A p.P226= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs781113422; called by muse, mutect2, varscan2
- CUX1 | c.990G>A p.Q330= (on ENST00000292535 / NM_181552.4; = p.Q341= on NM_001913.5) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs781811054, COSV52908656; called by muse, mutect2, varscan2
- CYLC2 | c.630A>G p.K210= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV66337529, COSV66338031; called by muse, mutect2, varscan2
- DLC1 | c.3894C>T p.T1298= (on ENST00000276297 / NM_001348081.2; = p.T861= on NM_006094.5) | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs780773136; called by muse, varscan2
- DNMT3B | c.723C>T p.A241= | Silent (SNP) | VAF 93/184 reads (51%) | catalogued as rs764811612, COSV52417037; called by muse, mutect2, varscan2
- ELMO1 | c.1494C>T p.S498= | Silent (SNP) | VAF 73/152 reads (48%) | called by muse, mutect2, varscan2
- ETAA1 | c.978T>G p.T326= | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- FLG | c.9957G>A p.P3319= | Silent (SNP) | VAF 51/213 reads (24%) | catalogued as rs774241945, COSV64242888; called by muse, mutect2, varscan2
- FRMPD1 | c.3603C>T p.F1201= | Silent (SNP) | VAF 29/254 reads (11%) | catalogued as rs200179129, COSV66699668; called by muse, mutect2, varscan2
- H3C10 | c.54C>T p.R18= | Silent (SNP) | VAF 54/127 reads (43%) | catalogued as COSV60798717; called by muse, mutect2, varscan2
- H4C5 | c.198G>A p.V66= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV63486077, COSV63486239; called by muse, mutect2, varscan2
- KCNJ9 | c.756C>T p.D252= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1366692318; called by muse, mutect2, varscan2
- KCTD2 | c.429T>C p.T143= | Silent (SNP) | VAF 19/95 reads (20%) | called by muse, mutect2, varscan2
- LDHB | c.909C>T p.S303= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as rs765924083; called by muse, mutect2, varscan2
- MYH7B | c.4143G>A p.V1381= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs747407098; called by muse, varscan2
- NCKAP1L | c.2814T>C p.G938= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs770744372; called by muse, mutect2, varscan2
- NCOA6 | c.2040C>T p.P680= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs963753484; called by muse, mutect2
- OR8H3 | c.729T>A p.S243= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV57908039, COSV57910347; called by muse, mutect2
- PCDHGA11 | c.813C>T p.D271= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs1045003805, COSV53964452; called by muse, mutect2, varscan2
- PCDHGA8 | c.1794G>A p.S598= | Silent (SNP) | VAF 24/135 reads (18%) | catalogued as rs769750411, COSV53921015; called by muse, mutect2, varscan2
- PLEKHA4 | c.1854C>T p.T618= | Silent (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- PPP2R5B | c.649C>T p.L217= | Silent (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- PRDM10 | c.1461T>C p.H487= | Silent (SNP) | VAF 94/180 reads (52%) | called by muse, mutect2, varscan2
- PRMT8 | c.867G>A p.S289= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as rs760968981, COSV54211398; called by muse, mutect2, varscan2
- PTPRT | c.3129C>A p.R1043= | Silent (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- REV3L | c.6828C>T p.Y2276= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs755842391; called by muse, mutect2, varscan2
- RTN4RL1 | c.729G>A p.P243= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs1388490270, COSV100486902; called by muse, mutect2, varscan2
- SCN5A | c.5328C>T p.S1776= (on ENST00000333535 / NM_198056.3; = p.S1775= on NM_000335.5) | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as rs1214009669; called by muse, mutect2, varscan2
- SLC4A7 | c.3363C>G p.L1121= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV55398006, COSV55398234; called by muse, mutect2, varscan2
- SYNE2 | c.837A>G p.A279= | Silent (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- TCERG1L | c.1117C>T p.L373= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV64048886; called by muse, mutect2, varscan2
- TMEM132A | c.750A>G p.V250= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- TMEM17 | c.588A>G p.E196= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as rs1440836685; called by muse, mutect2, varscan2
- TMEM94 | c.207G>A p.G69= | Silent (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- UNC5D | c.2214A>G p.P738= | Silent (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2, varscan2
- USP42 | c.882T>C p.C294= | Silent (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- USP43 | c.2661A>C p.P887= | Silent (SNP) | VAF 11/15 reads (73%) | called by muse, mutect2, varscan2
- USP6 | c.1491C>T p.C497= | Silent (SNP) | VAF 41/58 reads (71%) | catalogued as rs776194242; called by muse, mutect2, varscan2
- UTS2B | c.187A>C p.R63= | Silent (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- ZIM3 | c.213A>G p.E71= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as COSV54143528; called by muse, mutect2
- ZNF440 | c.84C>T p.L28= | Silent (SNP) | VAF 38/140 reads (27%) | called by muse, mutect2, varscan2
- MGAM | c.4618+128G>A | Intron (SNP) | VAF 37/114 reads (32%) | catalogued as COSV101527615; called by muse, mutect2, varscan2
- PSG5 | c.431-2936C>T | Intron (SNP) | VAF 34/185 reads (18%) | catalogued as rs536675616; called by muse, mutect2, varscan2
- RPL23AP42 | n.433G>A | RNA (SNP) | VAF 18/48 reads (38%) | catalogued as rs894468978; called by muse, mutect2, varscan2
